TARGET case TARGET-15-SJMPAL042943 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/53abb043-5b40-4a92-98c4-d9eb5d4fd127

Demographics
Sex at birth: female; Age at index: 0 years; Vital status: Dead; Days to death: 740 days (2.0 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 0.3 years (121 days); Year of diagnosis: 2007; Days to last follow up: 740 days (2.0 years).

Follow-up (1 entry)
- Days to follow up: 740 days (2.0 years); Event-free: no event (relapse, second malignancy or death) recorded through day 740; Year of follow up: 2009.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 453 ×10³/µL.

Biospecimens (2 samples)
- Sample TARGET-15-SJMPAL042943-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL042943-14A.1: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 740
- Protocol: BFM
- WBC at Diagnosis: 453
- Karyotype: MLL/AF4
- WHO ALAL Classification: MLL
- WHO Dx: MLL
